Somatic mutation profile of tumor specimen ALCH-AFJZ-TTP1-A (aliquot ALCH-AFJZ-TTP1-A-1-0-D-A679-36) from ALCHEMIST case ALCH-AFJZ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 74.2 years (27,102 days).
Specimen ALCH-AFJZ-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 25fb90d5-05de-4ece-96b6-af6f447c11d4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-AFJZ-NB1-A (Blood Derived Normal), aliquot ALCH-AFJZ-NB1-A-1-0-D-A679-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/64b31577-be67-482c-941d-9d385416a9a2

The open-access MAF lists 218 somatic variants for this specimen: 150 protein-altering or splice-affecting, 42 silent, 26 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 121, Silent 42, Nonsense Mutation 16, Intron 13, RNA 7, Frame Shift Del 6, Splice Region 3, Splice Site 2, 5'Flank 2, 5'UTR 2, In Frame Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NFE2L2 | c.242G>T p.G81V | Missense Mutation (SNP) | VAF 98/451 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67960014, COSV67960167, COSV67960618; called by muse, mutect2, varscan2
- TP53 | c.536A>G p.H179R | Missense Mutation (SNP) | VAF 58/246 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1057519991, COSV52661025, COSV52661712, COSV52690692, COSV52937418; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AC244197.3 | c.417T>A p.N139K | Missense Mutation (SNP) | VAF 189/373 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CD031058; called by muse, mutect2, varscan2
- ACSL6 | c.91G>T p.V31L (on ENST00000379240; = p.V56L on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 91/382 reads (24%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as COSV57300833; called by muse, mutect2, varscan2
- ANKRD30A | c.3208G>T p.E1070* (on ENST00000611781; = p.E1014* on NM_052997.2) | Nonsense Mutation (SNP) | VAF 47/201 reads (23%) | catalogued as rs767191588; called by muse, mutect2, varscan2
- ANKRD33 | c.538C>A p.L180M (on ENST00000340970 / NM_001304459.2; = p.L305M on NM_182608.4) | Missense Mutation (SNP) | VAF 18/249 reads (7%) | SIFT tolerated (0.37); PolyPhen benign (0.433); catalogued as COSV56605153; called by muse, mutect2
- BNIP2 | c.540G>T p.Q180H | Missense Mutation (SNP) | VAF 41/272 reads (15%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.852); catalogued as rs757186206; called by muse, mutect2, varscan2
- C2CD3 | c.6283A>G p.S2095G | Missense Mutation (SNP) | VAF 12/181 reads (7%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV100486826; called by muse, mutect2
- C4BPB | c.95G>A p.S32N | Missense Mutation (SNP) | VAF 39/188 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.595); catalogued as COSV99700166; called by muse, mutect2, varscan2
- CACNA1D | c.3338C>T p.S1113L (on ENST00000350061 / NM_001128840.3; = p.S1133L on NM_000720.4) | Missense Mutation (SNP) | VAF 40/522 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1363939471, COSV55444282; called by muse, mutect2
- CACNA1E | c.5077C>A p.R1693S | Missense Mutation (SNP) | VAF 29/171 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.053); catalogued as rs745342948, COSV62396016; called by muse, mutect2, varscan2
- CCDC85A | c.404G>T p.G135V | Missense Mutation (SNP) | VAF 145/370 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV68156638; called by muse, mutect2, varscan2
- CDHR1 | c.642T>C p.D214= | Splice Region (SNP) | VAF 70/319 reads (22%) | catalogued as COSV99058589; called by muse, mutect2, varscan2
- CFH | c.1312C>G p.P438A | Missense Mutation (SNP) | VAF 69/479 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.566); catalogued as COSV62776366; called by muse, mutect2, varscan2
- COL4A3 | c.4835C>A p.P1612Q | Missense Mutation (SNP) | VAF 12/270 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67421278; called by muse, mutect2
- COL9A1 | c.1486G>T p.G496C | Missense Mutation (SNP) | VAF 86/489 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57891451; called by muse, mutect2, varscan2
- DCC | c.439G>T p.E147* | Nonsense Mutation (SNP) | VAF 63/406 reads (16%) | catalogued as COSV59083452; called by muse, mutect2, varscan2
- DNAH10 | c.6293G>T p.R2098L (on ENST00000409039; = p.R2037L on NM_207437.3) | Missense Mutation (SNP) | VAF 30/142 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV69005929; called by muse, mutect2, varscan2
- ELFN2 | c.709G>A p.A237T | Missense Mutation (SNP) | VAF 29/125 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as rs1404259609; called by muse, mutect2, varscan2
- F13B | c.1318G>C p.E440Q | Missense Mutation (SNP) | VAF 67/443 reads (15%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.721); catalogued as rs766408940, COSV66373657; called by muse, mutect2, varscan2
- FILIP1 | c.763C>A p.Q255K | Missense Mutation (SNP) | VAF 60/353 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV52739187; called by muse, mutect2, varscan2
- FMN2 | c.2185G>T p.E729* | Nonsense Mutation (SNP) | VAF 108/615 reads (18%) | catalogued as COSV60451271; called by muse, mutect2, varscan2
- GLT1D1 | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 29/333 reads (9%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs753834116; called by muse, mutect2
- GPATCH1 | c.2345G>T p.G782V | Missense Mutation (SNP) | VAF 51/313 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0.039); catalogued as rs745713449; called by muse, mutect2, varscan2
- IFT52 | c.455T>C p.I152T | Missense Mutation (SNP) | VAF 98/436 reads (22%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs759737039; called by muse, mutect2, varscan2
- KLHDC7B | c.487G>A p.G163S (on ENST00000395676; = p.G804S on NM_138433.5) | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.011); catalogued as rs748205184; called by muse, varscan2
- LIMCH1 | c.1798G>T p.G600W | Missense Mutation (SNP) | VAF 80/298 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV58291202; called by muse, varscan2
- MAP2K3 | c.504G>T p.E168D (on ENST00000342679 / NM_145109.3; = p.E139D on NM_002756.4) | Missense Mutation (SNP) | VAF 37/274 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as COSV57568264; called by muse, mutect2, varscan2
- MRPS5 | c.890G>T p.R297I | Missense Mutation (SNP) | VAF 34/272 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.285); catalogued as rs1346164206, COSV55533315; called by muse, mutect2, varscan2
- MUC2 | c.3338C>T p.T1113M | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs762204897; called by muse, mutect2, varscan2
- NCAM2 | c.961G>A p.V321I | Missense Mutation (SNP) | VAF 37/203 reads (18%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as rs371257511, COSV53099152; called by muse, mutect2, varscan2
- NELL1 | c.11A>G p.D4G | Missense Mutation (SNP) | VAF 49/281 reads (17%) | SIFT tolerated, low confidence (0.16); PolyPhen probably damaging (0.956); catalogued as rs1357332832; called by muse, mutect2, varscan2
- OR10X1 | c.290T>G p.M97R | Missense Mutation (SNP) | VAF 63/413 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1175975137; called by muse, mutect2, varscan2
- OR14K1 | c.284G>T p.C95F | Missense Mutation (SNP) | VAF 58/364 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1161501961, COSV51720335; called by muse, mutect2, varscan2
- OR2T2 | c.328G>T p.G110* | Nonsense Mutation (SNP) | VAF 97/917 reads (11%) | catalogued as COSV100737548, COSV61618333; called by muse, mutect2, varscan2
- OR2T2 | c.329G>T p.G110V | Missense Mutation (SNP) | VAF 97/901 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770661335, COSV61617491, COSV61617669; called by muse, mutect2, varscan2
- OR2T4 | c.98C>A p.T33N | Missense Mutation (SNP) | VAF 69/406 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV63544083, COSV63544305; called by muse, mutect2, varscan2
- OR51E2 | c.52G>T p.G18* | Nonsense Mutation (SNP) | VAF 14/133 reads (11%) | catalogued as COSV67807945; called by muse, varscan2
- PKP4 | c.148C>T p.R50* | Nonsense Mutation (SNP) | VAF 57/197 reads (29%) | catalogued as rs921291987; called by muse, mutect2, varscan2
- REXO1 | c.3538del p.L1180Sfs*30 | Frame Shift Del (DEL) | VAF 8/60 reads (13%) | catalogued as COSV50085473; called by mutect2, pindel*, varscan2
- RICTOR | c.545G>A p.R182K | Missense Mutation (SNP) | VAF 35/260 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.573); catalogued as COSV57127524; called by muse, mutect2, varscan2
- RYR2 | c.12188C>T p.T4063M | Missense Mutation (SNP) | VAF 74/487 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.787); catalogued as rs1214925323, COSV63665103; called by muse, mutect2, varscan2
- S1PR1 | c.799G>C p.A267P | Missense Mutation (SNP) | VAF 46/172 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV59512513; called by muse, mutect2, varscan2
- SCN3A | c.1534C>A p.L512I | Missense Mutation (SNP) | VAF 130/610 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.025); catalogued as COSV51820778; called by muse, mutect2, varscan2
- SHANK1 | c.4888G>T p.E1630* | Nonsense Mutation (SNP) | VAF 10/38 reads (26%) | catalogued as COSV53253144; called by muse, varscan2
- SLIT3 | c.1702A>T p.K568* | Nonsense Mutation (SNP) | VAF 16/82 reads (20%) | catalogued as COSV60633590; called by muse, mutect2, varscan2
- SPTA1 | c.1067G>A p.R356H | Missense Mutation (SNP) | VAF 79/427 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.767); catalogued as rs796158885; called by muse, mutect2, varscan2
- SSH1 | c.1903A>G p.I635V | Missense Mutation (SNP) | VAF 97/523 reads (19%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0); catalogued as COSV58459490; called by muse, mutect2, varscan2
- TBC1D22A | c.1084G>A p.D362N | Missense Mutation (SNP) | VAF 26/342 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs760693157; called by muse, mutect2
- TDRD1 | c.514C>A p.R172S | Missense Mutation (SNP) | VAF 14/152 reads (9%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.998); catalogued as COSV99315174; called by muse, mutect2
- TICAM2 | c.41C>T p.S14F | Missense Mutation (SNP) | VAF 79/291 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.62); catalogued as rs762000950, COSV56694848; called by muse, mutect2, varscan2
- TMEM255B | c.221G>A p.G74D | Missense Mutation (SNP) | VAF 28/334 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs574056507, COSV64704601; called by muse, mutect2
- ZCCHC7 | c.748G>T p.G250C | Missense Mutation (SNP) | VAF 42/251 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100382821; called by muse, mutect2, varscan2
- ZNF567 | c.1583C>G p.T528R (on ENST00000536254 / NM_001322913.1; = p.T497R on NM_152603.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/206 reads (8%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as rs1466049188; called by muse, mutect2
- ZNF629 | c.1457A>G p.Y486C | Missense Mutation (SNP) | VAF 33/156 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs929386581, COSV52700574; called by muse, mutect2, varscan2
- ZNF638 | c.1502C>G p.S501* | Nonsense Mutation (SNP) | VAF 61/523 reads (12%) | catalogued as COSV52485577, COSV52493184; called by muse, mutect2, varscan2
- ZNF735 | c.29G>T p.S10I | Missense Mutation (SNP) | VAF 38/362 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); catalogued as COSV70035631; called by muse, mutect2
- ZNF99 | c.401A>G p.N134S | Missense Mutation (SNP) | VAF 29/154 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.347); catalogued as COSV68055080; called by muse, mutect2, varscan2
- ALPG | c.416A>G p.Q139R | Missense Mutation (SNP) | VAF 53/228 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.208); called by muse, mutect2, varscan2
- ALPK1 | c.2267A>T p.D756V | Missense Mutation (SNP) | VAF 23/115 reads (20%) | SIFT tolerated (0.23); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- ANO5 | c.22G>T p.E8* | Nonsense Mutation (SNP) | VAF 14/168 reads (8%) | called by muse, mutect2
- APBB1IP | c.453G>A p.Q151= | Splice Region (SNP) | VAF 39/146 reads (27%) | called by muse, mutect2, varscan2
- BCORL1 | c.214dup p.R72Pfs*22 | Frame Shift Ins (INS) | VAF 5/10 reads (50%) | called by mutect2, varscan2
- CACNA1H | c.5167G>T p.A1723S | Missense Mutation (SNP) | VAF 5/41 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- CAGE1 | c.876T>G p.S292R (on ENST00000512086; = p.S156R on NM_205864.3) | Missense Mutation (SNP) | VAF 51/193 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.663); called by muse, mutect2, varscan2
- CCDC138 | c.940T>G p.Y314D | Missense Mutation (SNP) | VAF 57/270 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.146); called by muse, mutect2, varscan2
- CHD7 | c.3502G>C p.D1168H | Missense Mutation (SNP) | VAF 54/261 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- CLCN6 | c.739_745delinsA p.A247_G249delinsR | In Frame Del (DEL) | VAF 32/165 reads (19%) | called by pindel, varscan2*
- CLDN1 | c.124A>T p.T42S | Missense Mutation (SNP) | VAF 152/397 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CLEC2L | c.192C>A p.D64E | Missense Mutation (SNP) | VAF 17/166 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- COL1A2 | c.2133+1G>T p.X711_splice | Splice Site (SNP) | VAF 152/710 reads (21%) | called by muse, mutect2, varscan2
- COMP | c.664del p.Q222Sfs*24 | Frame Shift Del (DEL) | VAF 23/89 reads (26%) | called by mutect2, pindel, varscan2
- CRIM1 | c.427A>G p.N143D | Missense Mutation (SNP) | VAF 15/166 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- CTNNA2 | c.1343T>G p.V448G | Missense Mutation (SNP) | VAF 41/265 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CTR9 | c.1750G>T p.G584W | Missense Mutation (SNP) | VAF 22/300 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2
- CUX2 | c.3966C>A p.D1322E | Missense Mutation (SNP) | VAF 51/246 reads (21%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); called by muse, mutect2, varscan2
- CYLC2 | c.763G>A p.D255N | Missense Mutation (SNP) | VAF 66/352 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- DES | c.7C>T p.Q3* | Nonsense Mutation (SNP) | VAF 14/85 reads (16%) | called by muse, mutect2, varscan2
- DNAH11 | c.2335G>C p.E779Q | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.812); called by muse, mutect2, varscan2
- DOK2 | c.524G>A p.G175E | Missense Mutation (SNP) | VAF 57/176 reads (32%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.526); called by muse, mutect2, varscan2
- DOT1L | c.3654G>T p.L1218F | Missense Mutation (SNP) | VAF 70/388 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.587); called by muse, varscan2
- DUSP26 | c.350A>T p.E117V | Missense Mutation (SNP) | VAF 58/194 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- F13B | c.629-1G>C p.X210_splice | Splice Site (SNP) | VAF 12/136 reads (9%) | called by muse, mutect2
- FETUB | c.556C>A p.Q186K | Missense Mutation (SNP) | VAF 26/316 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.02); called by muse, mutect2
- GJD4 | c.988C>G p.Q330E | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- HNF4A | c.1393C>A p.Q465K | Missense Mutation (SNP) | VAF 26/239 reads (11%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- HNRNPUL1 | c.1864G>A p.G622S | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- ICE1 | c.5315A>G p.N1772S | Missense Mutation (SNP) | VAF 67/439 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- IL16 | c.2492G>T p.R831L (on ENST00000302987 / NM_172217.5; = p.R130L on NM_004513.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/118 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- IRS1 | c.2423C>T p.S808F | Missense Mutation (SNP) | VAF 47/167 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ITGAM | c.1463G>C p.G488A | Missense Mutation (SNP) | VAF 14/144 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KCNH7 | c.351C>A p.N117K | Missense Mutation (SNP) | VAF 37/172 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KHDRBS1 | c.61A>G p.M21V | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIAA1841 | c.2144G>T p.G715V | Missense Mutation (SNP) | VAF 92/435 reads (21%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- KIF26A | c.2683G>T p.A895S | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT tolerated (0.47); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- LIPC | c.941T>C p.L314P | Missense Mutation (SNP) | VAF 71/406 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LRIT1 | c.311G>A p.R104Q | Missense Mutation (SNP) | VAF 24/135 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- LRP1B | c.3226G>T p.E1076* | Nonsense Mutation (SNP) | VAF 52/344 reads (15%) | called by muse, mutect2, varscan2
- MTR | c.1306G>T p.A436S | Missense Mutation (SNP) | VAF 113/623 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- MUC16 | c.30470T>C p.F10157S | Missense Mutation (SNP) | VAF 24/170 reads (14%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0); called by muse, mutect2
- MUC19 | c.875C>T p.P292L | Missense Mutation (SNP) | VAF 30/134 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- NALCN | c.2575A>G p.N859D | Missense Mutation (SNP) | VAF 21/159 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NELL1 | c.10G>T p.D4Y | Missense Mutation (SNP) | VAF 49/281 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- NUP133 | c.1563G>C p.L521F | Missense Mutation (SNP) | VAF 34/223 reads (15%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- OR52B6 | c.236T>A p.M79K | Missense Mutation (SNP) | VAF 25/175 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- OR6F1 | c.120T>G p.S40R | Missense Mutation (SNP) | VAF 64/380 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PABPC3 | c.1225C>G p.Q409E | Missense Mutation (SNP) | VAF 56/433 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.024); called by muse, varscan2
- PCDH15 | c.3347T>C p.L1116P | Missense Mutation (SNP) | VAF 47/205 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- PCDHB3 | c.2164G>A p.V722M | Missense Mutation (SNP) | VAF 46/184 reads (25%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PCNX2 | c.35del p.G12Afs*56 | Frame Shift Del (DEL) | VAF 19/163 reads (12%) | called by mutect2, pindel, varscan2
- PEAK1 | c.159C>A p.H53Q | Missense Mutation (SNP) | VAF 37/175 reads (21%) | SIFT tolerated (0.65); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PGM5 | c.1561C>A p.L521M | Missense Mutation (SNP) | VAF 43/195 reads (22%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.628); called by muse, mutect2, varscan2
- PIP4K2A | c.226A>G p.N76D | Missense Mutation (SNP) | VAF 72/256 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- POM121L2 | c.892C>A p.P298T | Missense Mutation (SNP) | VAF 140/371 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- PON3 | c.369C>A p.D123E | Missense Mutation (SNP) | VAF 16/474 reads (3%) | SIFT deleterious (0.05); PolyPhen benign (0.308); called by muse, mutect2
- PPIAL4A | c.261C>A p.N87K | Missense Mutation (SNP) | VAF 56/942 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2
- PRDM16 | c.992A>T p.H331L | Missense Mutation (SNP) | VAF 42/150 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PRR23B | c.602C>A p.A201D | Missense Mutation (SNP) | VAF 16/106 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- RORA | c.160A>G p.S54G | Missense Mutation (SNP) | VAF 18/142 reads (13%) | SIFT tolerated (0.3); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- SCN11A | c.2445C>A p.S815R | Missense Mutation (SNP) | VAF 17/121 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- SELP | c.1660T>A p.C554S | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SEMA5A | c.85C>T p.Q29* | Nonsense Mutation (SNP) | VAF 42/206 reads (20%) | called by muse, mutect2, varscan2
- SERPINA6 | c.271C>G p.Q91E | Missense Mutation (SNP) | VAF 62/284 reads (22%) | SIFT tolerated (0.54); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SLC6A13 | c.589G>T p.G197W | Missense Mutation (SNP) | VAF 20/149 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SLCO1B3 | c.2061T>G p.D687E | Missense Mutation (SNP) | VAF 50/223 reads (22%) | SIFT tolerated (0.34); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SPDYE6 | c.254A>T p.E85V | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.177); called by mutect2, varscan2
- SPTB | c.2197G>T p.A733S | Missense Mutation (SNP) | VAF 86/359 reads (24%) | SIFT tolerated (0.21); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- STAMBP | c.529G>T p.E177* | Nonsense Mutation (SNP) | VAF 11/284 reads (4%) | called by muse, mutect2
- TMCO3 | c.1539+4A>T | Splice Region (SNP) | VAF 30/228 reads (13%) | called by muse, mutect2, varscan2
- TOP1 | c.2165A>G p.N722S | Missense Mutation (SNP) | VAF 53/302 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.428); called by muse, mutect2, varscan2
- TTLL5 | c.119C>G p.P40R | Missense Mutation (SNP) | VAF 30/184 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- TTN | c.90820G>C p.A30274P (on ENST00000591111; = p.A22850P on NM_003319.4) | Missense Mutation (SNP) | VAF 4/70 reads (6%) | PolyPhen benign (0.186); called by muse, mutect2
- TTN | c.41593del p.D13865Ifs*8 (on ENST00000591111; = p.D6441Ifs*8 on NM_003319.4) | Frame Shift Del (DEL) | VAF 72/341 reads (21%) | called by mutect2, pindel, varscan2
- UNC13A | c.381del p.F127Lfs*5 | Frame Shift Del (DEL) | VAF 15/96 reads (16%) | called by mutect2, pindel, varscan2
- UNG | c.756G>T p.L252F (on ENST00000242576 / NM_080911.3; = p.L243F on NM_003362.4) | Missense Mutation (SNP) | VAF 78/564 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- VEGFA | c.619A>G p.K207E (on ENST00000523873 / NM_001171623.1; = p.K370E on NM_003376.6) | Missense Mutation (SNP) | VAF 419/1043 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- VWDE | c.3059C>G p.S1020C | Missense Mutation (SNP) | VAF 14/166 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- WDR86 | c.551G>T p.C184F | Missense Mutation (SNP) | VAF 27/143 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.871); called by muse, mutect2, varscan2
- WRN | c.2496C>A p.D832E | Missense Mutation (SNP) | VAF 93/434 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZFP57 | c.1544G>T p.G515V | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- ZNF224 | c.1948A>T p.K650* | Nonsense Mutation (SNP) | VAF 66/331 reads (20%) | called by muse, mutect2, varscan2
- ZNF324B | c.603G>C p.E201D | Missense Mutation (SNP) | VAF 21/203 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.192); called by muse, mutect2, varscan2
- ZNF479 | c.1048G>T p.E350* | Nonsense Mutation (SNP) | VAF 104/282 reads (37%) | called by muse, mutect2, varscan2
- ZNF519 | c.1097A>T p.H366L | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ZNF541 | c.3170T>C p.I1057T | Missense Mutation (SNP) | VAF 33/149 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.356); called by muse, mutect2, varscan2
- ZNF568 | c.893G>T p.R298I | Missense Mutation (SNP) | VAF 33/182 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF638 | c.1789C>T p.L597F | Missense Mutation (SNP) | VAF 73/469 reads (16%) | SIFT tolerated (0.28); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF682 | c.836A>G p.H279R | Missense Mutation (SNP) | VAF 38/222 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF865 | c.463del p.H155Tfs*8 | Frame Shift Del (DEL) | VAF 4/19 reads (21%) | called by mutect2, pindel, varscan2
- ZNF99 | c.983T>A p.L328H | Missense Mutation (SNP) | VAF 72/397 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ABCB7 | c.1104G>A p.L368= (on ENST00000373394 / NM_001271696.3; = p.L369= on NM_004299.6) | Silent (SNP) | VAF 60/151 reads (40%) | called by muse, mutect2, varscan2
- ABCG8 | c.921C>T p.I307= | Silent (SNP) | VAF 20/340 reads (6%) | catalogued as rs780422381, COSV55394886; called by muse, mutect2
- ACTG1 | c.957C>G p.A319= | Silent (SNP) | VAF 74/328 reads (23%) | called by muse, mutect2, varscan2
- ANGPTL6 | c.948T>C p.Y316= | Silent (SNP) | VAF 14/94 reads (15%) | called by muse, mutect2
- BCAT1 | c.1023T>A p.S341= | Silent (SNP) | VAF 45/195 reads (23%) | called by muse, mutect2, varscan2
- BCOR | c.4254C>A p.P1418= (on ENST00000378444 / NM_001123385.2; = p.P1384= on NM_017745.6) | Silent (SNP) | VAF 19/361 reads (5%) | called by muse, mutect2
- CTNNA3 | c.2484C>T p.A828= | Silent (SNP) | VAF 60/278 reads (22%) | catalogued as COSV101041217; called by muse, varscan2
- DCAF12L1 | c.1056C>A p.G352= | Silent (SNP) | VAF 33/71 reads (46%) | catalogued as COSV64421142, COSV64421668; called by muse, mutect2, varscan2
- DIP2A | c.861A>G p.P287= | Silent (SNP) | VAF 40/138 reads (29%) | called by muse, mutect2, varscan2
- ERBB3 | c.144A>G p.T48= | Silent (SNP) | VAF 117/620 reads (19%) | catalogued as rs764891356; called by muse, mutect2, varscan2
- FBLN1 | c.51C>T p.L17= | Silent (SNP) | VAF 4/18 reads (22%) | called by muse, varscan2
- GOLGA3 | c.96C>T p.G32= | Silent (SNP) | VAF 23/83 reads (28%) | catalogued as rs1442009469; called by muse, mutect2, varscan2
- GRIK5 | c.2655C>G p.L885= | Silent (SNP) | VAF 33/141 reads (23%) | catalogued as rs1555870277; called by muse, mutect2, varscan2
- HTR1B | c.822T>C p.V274= | Silent (SNP) | VAF 36/414 reads (9%) | called by muse, mutect2
- ICAM5 | c.492G>C p.L164= | Silent (SNP) | VAF 36/173 reads (21%) | called by muse, mutect2, varscan2
- IL18R1 | c.522C>T p.N174= | Silent (SNP) | VAF 45/232 reads (19%) | catalogued as rs201629380; called by muse, mutect2, varscan2
- ITGAM | c.1464G>T p.G488= | Silent (SNP) | VAF 14/137 reads (10%) | called by muse, mutect2
- ITPR2 | c.6993C>T p.G2331= | Silent (SNP) | VAF 70/303 reads (23%) | called by muse, mutect2, varscan2
- KREMEN1 | c.1083C>T p.T361= (on ENST00000407188; = p.T363= on NM_032045.5) | Silent (SNP) | VAF 150/590 reads (25%) | called by muse, mutect2, varscan2
- LIPC | c.942G>T p.L314= | Silent (SNP) | VAF 69/403 reads (17%) | called by muse, mutect2, varscan2
- LPAR3 | c.372C>T p.A124= | Silent (SNP) | VAF 42/166 reads (25%) | catalogued as rs368870250; called by muse, mutect2, varscan2
- LRFN2 | c.111G>T p.L37= | Silent (SNP) | VAF 8/48 reads (17%) | called by muse, mutect2, varscan2
- LTBP1 | c.2649C>A p.I883= (on ENST00000404816 / NM_206943.4; = p.I557= on NM_000627.4) | Silent (SNP) | VAF 24/318 reads (8%) | called by muse, mutect2
- MRPS5 | c.891A>G p.R297= | Silent (SNP) | VAF 34/273 reads (12%) | called by muse, mutect2, varscan2
- NCOA6 | c.153C>T p.A51= | Silent (SNP) | VAF 61/316 reads (19%) | catalogued as COSV62868496; called by muse, mutect2, varscan2
- NLGN1 | c.480C>G p.V160= | Silent (SNP) | VAF 14/145 reads (10%) | catalogued as COSV64327248; called by muse, mutect2
- NLRP8 | c.1866A>T p.V622= | Silent (SNP) | VAF 30/168 reads (18%) | catalogued as COSV52586148; called by muse, mutect2, varscan2
- OCSTAMP | c.1185G>T p.R395= | Silent (SNP) | VAF 4/25 reads (16%) | catalogued as rs537737693; called by mutect2, varscan2
- OR2C3 | c.360C>T p.S120= | Silent (SNP) | VAF 55/281 reads (20%) | called by muse, mutect2, varscan2
- OR4K15 | c.636C>A p.A212= (on ENST00000305051; = p.A188= on NM_001005486.1) | Silent (SNP) | VAF 63/277 reads (23%) | called by muse, mutect2, varscan2
- OR6C75 | c.381T>A p.P127= | Silent (SNP) | VAF 52/336 reads (15%) | called by muse, varscan2
- OR7C2 | c.415C>A p.R139= | Silent (SNP) | VAF 68/390 reads (17%) | called by muse, mutect2, varscan2
- SCN1A | c.1506G>A p.K502= | Silent (SNP) | VAF 89/447 reads (20%) | called by muse, mutect2, varscan2
- SCRIB | c.3339C>T p.I1113= | Silent (SNP) | VAF 28/127 reads (22%) | called by muse, mutect2, varscan2
- SLC51A | c.237C>A p.T79= | Silent (SNP) | VAF 60/294 reads (20%) | called by muse, varscan2
- STARD3 | c.1017C>T p.G339= | Silent (SNP) | VAF 4/33 reads (12%) | catalogued as rs776385927; called by mutect2, varscan2
- THEGL | c.660G>T p.L220= | Silent (SNP) | VAF 46/142 reads (32%) | called by muse, varscan2
- TMEM132C | c.1860A>G p.E620= | Silent (SNP) | VAF 14/206 reads (7%) | called by muse, mutect2
- TRAPPC9 | c.1062C>T p.V354= | Silent (SNP) | VAF 106/688 reads (15%) | catalogued as COSV66902275; called by muse, mutect2, varscan2
- TRPC4 | c.858T>C p.L286= | Silent (SNP) | VAF 15/103 reads (15%) | called by muse, varscan2
- TTN | c.70440C>A p.I23480= (on ENST00000591111; = p.I16056= on NM_003319.4) | Silent (SNP) | VAF 143/520 reads (28%) | catalogued as COSV100600377; called by muse, mutect2, varscan2
- ZSCAN12 | c.966A>T p.I322= | Silent (SNP) | VAF 100/282 reads (35%) | called by muse, mutect2, varscan2
- AC136628.2 | n.182C>A | RNA (SNP) | VAF 54/180 reads (30%) | called by muse, mutect2, varscan2
- ADAM10 | c.207-10509G>T | Intron (SNP) | VAF 45/246 reads (18%) | called by muse, mutect2, varscan2
- AL162726.3 | n.255+83178G>T | Intron (SNP) | VAF 84/453 reads (19%) | called by muse, mutect2, varscan2
- CAGE1 | c.2005-307A>G | Intron (SNP) | VAF 11/104 reads (11%) | called by muse, mutect2, varscan2
- CEACAM3 | c.425-1649A>G | Intron (SNP) | VAF 37/315 reads (12%) | catalogued as rs782168877; called by muse, mutect2, varscan2
- CLC | c.-34A>G | 5'UTR (SNP) | VAF 22/97 reads (23%) | called by muse, mutect2, varscan2
- CLEC4A | c.299-1223G>T | Intron (SNP) | VAF 111/493 reads (23%) | called by muse, mutect2, varscan2
- ECHDC1 | c.435-255dup | Intron (INS) | VAF 35/179 reads (20%) | called by mutect2, pindel, varscan2
- FMR1 | c.1472-39A>T | Intron (SNP) | VAF 10/52 reads (19%) | catalogued as rs1167026205, COSV54424178; called by muse, varscan2
- HSPA7 | n.902G>A | RNA (SNP) | VAF 68/378 reads (18%) | catalogued as rs746309497; called by muse, mutect2, varscan2
- IL16 | c.-227C>T | 5'UTR (SNP) | VAF 18/118 reads (15%) | called by muse, mutect2, varscan2
- IRF2 | c.529+937A>T | Intron (SNP) | VAF 44/226 reads (19%) | called by muse, mutect2, varscan2
- MIR519C | n.84G>C | RNA (SNP) | VAF 30/132 reads (23%) | called by muse, varscan2
- MIR6511A1 | chr16:14929312 C>A | 3'Flank (SNP) | VAF 27/472 reads (6%) | catalogued as rs201513913; called by muse, mutect2
- NCKAP5L | c.193-18G>C | Intron (SNP) | VAF 58/242 reads (24%) | called by muse, varscan2
- NELL1 | c.1549+54949A>G | Intron (SNP) | VAF 59/334 reads (18%) | called by muse, mutect2, varscan2
- OR2M1P | n.516G>C | RNA (SNP) | VAF 67/394 reads (17%) | called by muse, mutect2, varscan2
- PKD1P6 | n.4518+107A>T | Intron (SNP) | VAF 48/186 reads (26%) | catalogued as rs1168707911; called by muse, mutect2, varscan2
- PSG9 | c.1243+89C>A | Intron (SNP) | VAF 30/85 reads (35%) | called by muse, varscan2
- RBBP4 | c.*2079G>T | 3'UTR (SNP) | VAF 47/167 reads (28%) | catalogued as rs768823697; called by muse, mutect2, varscan2
- SLC5A5 | c.1171+29G>T | Intron (SNP) | VAF 62/308 reads (20%) | called by muse, mutect2, varscan2
- SNORD116-16 | n.64A>T | RNA (SNP) | VAF 68/448 reads (15%) | called by muse, mutect2
- SNORD116-16 | n.66A>C | RNA (SNP) | VAF 62/432 reads (14%) | called by muse, mutect2
- SPATA31C1 | n.2377C>G | RNA (SNP) | VAF 29/377 reads (8%) | called by muse, mutect2
- TRAV22 | chr14:22066276 C>A | 5'Flank (SNP) | VAF 45/140 reads (32%) | called by muse, mutect2, varscan2
- USP2 | chr11:119381840 C>A | 5'Flank (SNP) | VAF 36/404 reads (9%) | called by muse, mutect2
